Somatic mutation profile of tumor specimen TARGET-10-PATHJF-09A (aliquot TARGET-10-PATHJF-09A-01D) from TARGET case TARGET-10-PATHJF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.2 years (3,743 days).
Specimen TARGET-10-PATHJF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4fd3010-df61-485b-ae16-df302122441f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATHJF-14A (Bone Marrow Normal), aliquot TARGET-10-PATHJF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f1abf56-1eaf-4d3e-9dcf-5a42506685cf

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Ins 2, Nonsense Mutation 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2035C>T p.R679C (on ENST00000460911 / NM_001203247.2; = p.R684C on NM_004456.5) | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs587783626, CM1110542, COSV57449598, COSV57463748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 88/160 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NAA10 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs797044868, COSV100892473, COSV64169548; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327426602, COSV51402426; called by muse, mutect2, varscan2
- DACT2 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs371509290; called by muse, mutect2, varscan2
- HCN1 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 161/359 reads (45%) | catalogued as rs1335989876, COSV57501102; called by muse, mutect2, varscan2
- MMP11 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs199515716, COSV53155775; called by muse, mutect2, varscan2
- NOTCH1 | c.5027T>A p.V1676D | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53026269; called by muse, varscan2
- PIK3R6 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs1191793942, COSV61002366; called by muse, mutect2, varscan2
- PTEN | c.439_440dup p.A148Rfs*6 | Frame Shift Ins (INS) | VAF 67/96 reads (70%) | catalogued as COSV64292251; called by mutect2, pindel, varscan2
- RPUSD3 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59613911; called by muse, mutect2
- RYR1 | c.4747C>T p.R1583C | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs754476250, CM129449, COSV62093269; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SULT1C3 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61252740; called by muse, mutect2
- TENM4 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.545); catalogued as COSV53618154; called by muse, mutect2, varscan2
- BAZ1A | c.2012dup p.E672Gfs*5 | Frame Shift Ins (INS) | VAF 76/194 reads (39%) | called by mutect2, pindel, varscan2
- CNOT3 | c.258G>A p.T86= | Splice Region (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- FXYD6P3 | n.151-1G>A | Splice Site (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- OBSCN | c.19909C>A p.Q6637K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- PCSK5 | c.3757C>A p.H1253N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- CCT3 | c.435C>T p.D145= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1275C>T p.T425= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as rs782769711, COSV100251080; called by muse, mutect2, varscan2
- PCDHA5 | c.1668C>T p.D556= | Silent (SNP) | VAF 74/149 reads (50%) | catalogued as rs1554129352, COSV65348905; called by muse, mutect2, varscan2
- SLC4A2 | c.3093C>A p.G1031= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
